Somatic mutation profile of tumor specimen MP2PRT-PAUGDC-TMP1-A (aliquot MP2PRT-PAUGDC-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAUGDC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (976 days).
Specimen MP2PRT-PAUGDC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86213882-bb31-48c7-8262-8b6c9cc8bdeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUGDC-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUGDC-NM1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f1a3bf35-7ec1-47a6-954b-d631d6d1ad8e

The open-access MAF lists 16 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, 5'UTR 2, Silent 2, Splice Region 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CNTRL | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV53049054; called by muse, mutect2
- FGF14 | c.116C>T p.S39L | Missense Mutation (SNP) | VAF 35/379 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs1346163352; called by muse, mutect2, varscan2
- GDAP1L1 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 50/593 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.287); catalogued as COSV61159038; called by muse, mutect2
- GRK6 | c.1269C>T p.L423= | Splice Region (SNP) | VAF 16/299 reads (5%) | catalogued as COSV62684624; called by muse, mutect2
- SLC25A48 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 21/499 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV50849017; called by muse, mutect2
- WNT2 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.154); catalogued as rs143749132, COSV55414144; called by muse, mutect2
- DOCK1 | c.1191A>C p.K397N | Missense Mutation (SNP) | VAF 109/283 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FMN1 | c.180C>G p.I60M | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.359); called by muse, mutect2
- IGHV1-46 | chr14:106511105 TCACACTGTGTCTC>CCTTGG | Missense Mutation (DEL) | VAF 21/97 reads (22%) | called by pindel, varscan2*
- MECOM | c.884C>T p.T295I (on ENST00000468789 / NM_001105078.4; = p.T483I on NM_004991.4) | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.397); called by muse, mutect2
- WWC2 | c.1735C>T p.H579Y | Missense Mutation (SNP) | VAF 67/331 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.369); called by muse, mutect2, varscan2
- KCNA4 | c.1692C>T p.N564= | Silent (SNP) | VAF 18/430 reads (4%) | called by muse, mutect2
- RALGDS | c.1347C>T p.L449= | Silent (SNP) | VAF 31/642 reads (5%) | catalogued as rs771593716, COSV64427313; called by muse, mutect2
- COP1 | c.-84G>A | 5'UTR (SNP) | VAF 31/664 reads (5%) | called by muse, mutect2
- IGHV3-43 | chr14:106470263 ins CCCGGGA | 3'Flank (INS) | VAF 4/46 reads (9%) | called by mutect2, pindel
- MORN2 | c.-165C>T | 5'UTR (SNP) | VAF 42/454 reads (9%) | called by muse, mutect2
